Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A59E, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A59E-01A (Primary Tumor).

[page 1 of 2]
ICD-3
Carcinoma/Mixed
Mullerian Tumor, malignant
8950/3
Site C&F Myometrium C54.2
path Endometrium C54.1
JED 4/2/13

Specimens Submitted:

- 1: Uterus, cervix bilateral fallopian tubes and ovaries
- 2: Omentum
- 3: Cul-de-sac tumor
- 4: Rectal serosal tumor
- 5: Rectal serosal tumor #2
- 6: Left external iliac lymph node
- 7: Tumor from transverse colon
- 8: Falciform ligament nodule
- 9: Falciform ligament
- 10: Right diaphragm tumor
- 11: Small bowel mesenteric nodule
- 12: Xiphoid
- 13: Right supradiaphragmatic node

DIAGNOSIS:

1. Uterus, cervix bilateral fallopian tubes and ovaries:

Tumor Type:

Carcinosarcoma (Malignant mullerian mixed tumor) of endometrium
with heterologous differentiation

Myometrial Invasion:

(>50%)

Measures 10 mm in maximum depth

Myometrium thickness measures 14 mm in the area of maximal tumor

invasion

Endocervical Invasion:

Mucosa and stroma

Depth of cervical stromal invasion:

Measures 10 mm

Cervical wall thickness measures 16 mm in the area of maximum

tumor invasion

Lymphovascular invasion:

Identified

Endometrium:

Exhibits a polyp

Myometrium:

Exhibits adenomyosis

** Continued on next page **

[page 2 of 2]
Exhibits one leiomyoma

Adnexa:

Unremarkable

-
2. Omentum; omentectomy:
- Metastatic carcinoma
3. Cul-de-sac tumor; excision:
- Metastatic carcinoma
4. Rectal serosal tumor; excision:
- Metastatic carcinoma.
5. Rectal serosal tumor #2; excision:
- Metastatic carcinoma.
6. Left external iliac lymph node; dissection:
- Two benign lymph nodes (0/2).
7. Tumor from transverse colon; excision:
- Metastatic carcinoma
8. Falciform ligament nodule; excision:
- Metastatic carcinoma
9. Falciform ligament; excision:
- Metastatic carcinoma
10. Right diaphragm tumor; excision:
- Metastatic carcinoma
11. Small bowel mesenteric nodule; excision:
- Metastatic carcinoma
12. Xiphoid; excision:
- Benign cartilage and fibroconnective tissue.
13. Right supradiaphragmatic lymph nodes; dissection:
- Metastatic carcinoma in lymph nodes (2/3).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file d56608d3-d62b-45e7-bbca-4072a1ca9b33 (TCGA-N5-A59E.326826BF-E3D8-42FC-AFFE-B6F454F1C0BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).